TARGET case TARGET-30-PASCEW — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8d5f5a51-ac88-57f5-b0b1-d4d9682c897d

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 1,129 days (3.1 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C47.4; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of abdomen; Classification of tumor: primary; Age at diagnosis: 4.0 years (1,477 days); Year of diagnosis: 2008; Days to last follow up: 1,129 days (3.1 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4.
   Pathology details: Percent tumor nuclei: 60.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ALTE05N1.
   Treatment given: Protocol identifier: ANBL0532.
   Treatment given: Protocol identifier: ADVL0911.
   Treatment given: Protocol identifier: ADVL0812.

Follow-up (2 entries)
- Days to follow up: 700 days (1.9 years); Days to first event: 700 days (1.9 years); First event: Relapse.
- Days to follow up: 1,129 days (3.1 years); Year of follow up: 2011.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASCEW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-30-PASCEW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1129
- Protocol: ANBL00B1, ANBL0532, ALTE05N1, ADVL0812, ADVL0911
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.12
- Histology: Unfavorable
- Site of Relapse: Metastases only
